Somatic mutation profile of tumor specimen TARGET-30-PARLTG-01A (aliquot TARGET-30-PARLTG-01A-01D) from TARGET case TARGET-30-PARLTG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 6.7 years (2,436 days).
Specimen TARGET-30-PARLTG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be7d0641-f787-4063-b355-ab093ff0cc7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARLTG-10A (Blood Derived Normal), aliquot TARGET-30-PARLTG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e56f1445-77ea-4dca-88bc-f15b5046e512

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3521T>G p.F1174C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519697, COSV66558767, COSV66560921; ClinVar: pathogenic; called by muse, varscan2
- A2ML1 | c.4317C>A p.Y1439* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV55298474; called by muse, mutect2, varscan2
- AFG3L2 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV52317402; called by muse, mutect2, varscan2
- ARHGAP31 | c.3284G>A p.C1095Y | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.564); catalogued as COSV51798917; called by muse, mutect2, varscan2
- FST | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56816847; called by muse, varscan2
- GPRC5A | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV50008734; called by muse, mutect2, varscan2
- GRIN2B | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV74207841; called by muse, mutect2, varscan2
- MAP2K7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607626; called by muse, mutect2, varscan2
- NLRP9 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV60467757; called by muse, mutect2, varscan2
- NWD1 | c.1405T>A p.C469S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.675); catalogued as COSV100342638, COSV60351654; called by muse, mutect2, varscan2
- OR11H4 | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as COSV59560937; called by muse, mutect2, varscan2
- RBM26 | c.1407G>T p.L469F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.915); catalogued as COSV57399910; called by muse, mutect2, varscan2
- STON1 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs370031309, COSV59138250; called by muse, mutect2, varscan2
- DNAH2 | c.3681C>G p.L1227= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs758074890, COSV66727235; called by muse, mutect2
- KRTAP27-1 | c.462G>A p.L154= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MCOLN2 | c.1287G>T p.L429= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV52299608; called by muse, mutect2, varscan2
- TNNI1 | c.111C>G p.R37= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV60189173; called by muse, mutect2
- BTN2A3P | n.1619T>A | RNA (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
